Somatic mutation profile of tumor specimen 0DRSTZ from CCDI case PBCGWZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 8.4 years (3,064 days).
Specimen 0DRSTZ: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccf775e-d59f-4451-a9ec-fadb02a8488b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRSSC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/793b0d87-b24a-4b39-bd89-d64a9382485b

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNT2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 33/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583460; called by muse, mutect2
- KCNB2 | c.539G>T p.W180L | Missense Mutation (SNP) | VAF 42/389 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV101578830; called by muse, mutect2, varscan2
- MAP3K5 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs542409556; called by muse, mutect2, varscan2
- ACOT1 | c.974A>G p.D325G | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNAJC15 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ELFN2 | c.138C>T p.Y46= | Silent (SNP) | VAF 151/302 reads (50%) | catalogued as rs148502713; called by muse, mutect2, varscan2
- HECW1 | c.174C>T p.H58= | Silent (SNP) | VAF 53/271 reads (20%) | catalogued as rs906767913, COSV67820621, COSV67827293; called by muse, mutect2, varscan2
- HNRNPCL2 | c.132G>A p.A44= | Silent (SNP) | VAF 297/673 reads (44%) | called by muse, varscan2
- TRIM31 | c.678C>T p.N226= | Silent (SNP) | VAF 217/509 reads (43%) | catalogued as rs767124026; called by muse, mutect2
- TUB | c.1479C>T p.A493= (on ENST00000299506 / NM_177972.3; = p.A548= on NM_003320.4) | Silent (SNP) | VAF 62/430 reads (14%) | called by muse, mutect2, varscan2
